Somatic mutation profile of tumor specimen TCGA-G9-6343-01A (aliquot TCGA-G9-6343-01A-21D-1961-08) from TCGA case TCGA-G9-6343, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.5 years (22,843 days).
Specimen TCGA-G9-6343-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31015904-b5c1-4f58-bfed-b404d8115523.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6343-10A (Blood Derived Normal), aliquot TCGA-G9-6343-10A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e86b261-e77f-4061-8b9a-57bdd8e465a1

The open-access MAF lists 28 somatic variants for this specimen: 17 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 10, Translation Start Site 1, Nonstop Mutation 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADH1C | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV72463461; called by muse, mutect2, varscan2
- AMZ1 | c.725G>A p.G242D | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV56689185; called by muse, mutect2, varscan2
- APBB3 | c.1091T>G p.F364C (on ENST00000357560 / NM_133173.2; = p.F371C on NM_006051.3) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60054077; called by muse, mutect2
- CFAP65 | c.2053A>G p.M685V | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV58566496; called by muse, mutect2, varscan2
- ETFDH | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV57016603; called by muse, mutect2, varscan2
- GSDMC | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as COSV52699529; called by muse, mutect2, varscan2
- GUF1 | c.1461A>C p.K487N | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.658); catalogued as COSV55785025; called by muse, mutect2
- MYH4 | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV55126660; called by muse, mutect2
- OR2B11 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV59511598; called by muse, mutect2, varscan2
- OR6C2 | c.665C>A p.T222K | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.851); catalogued as rs759876401, COSV59517021; called by muse, mutect2
- POLR3A | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV64932146; called by muse, mutect2, varscan2
- PPFIBP2 | c.1963A>G p.R655G | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV55082639; called by muse, mutect2
- PPP1R14C | c.498A>C p.*166Cext*21 | Nonstop Mutation (SNP) | VAF 5/40 reads (13%) | catalogued as COSV63176611; called by muse, mutect2
- RP1 | c.6331G>A p.V2111I | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV55116921; called by muse, mutect2, varscan2
- SP4 | c.2098A>G p.T700A | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56026634; called by muse, mutect2
- ZNF208 | c.1316A>G p.N439S | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68112781; called by muse, mutect2
- TOPORS | c.369_370del p.F123Lfs*14 | Frame Shift Del (DEL) | VAF 17/128 reads (13%) | called by mutect2, pindel, varscan2
- C1orf94 | c.1788A>C p.I596= (on ENST00000488417 / NM_001134734.2; = p.I406= on NM_032884.5) | Silent (SNP) | VAF 11/109 reads (10%) | catalogued as COSV64915924; called by muse, mutect2
- ENKD1 | c.90A>G p.Q30= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs771343349, COSV54677781; called by muse, mutect2, varscan2
- FZD8 | c.723G>T p.V241= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV65968528; called by muse, mutect2, varscan2
- GJB4 | c.114G>A p.V38= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV58357137; called by muse, mutect2
- MUC16 | c.4155C>T p.T1385= | Silent (SNP) | VAF 18/153 reads (12%) | catalogued as COSV67495336; called by muse, mutect2, varscan2
- NRXN1 | c.894A>G p.Q298= | Silent (SNP) | VAF 8/120 reads (7%) | catalogued as COSV58449464, COSV58495226; called by muse, mutect2
- PDGFB | c.579G>A p.P193= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as rs149693918, COSV58645864, COSV58650168; called by muse, mutect2
- PIK3CA | c.3105T>G p.A1035= | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as COSV56000122; called by muse, mutect2
- PTPRB | c.5760C>T p.I1920= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV54254029; called by muse, mutect2, varscan2
- ZNF394 | c.513C>T p.R171= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV61794498; called by muse, mutect2
- TP53AIP1 | c.141+28G>T | Intron (SNP) | VAF 15/111 reads (14%) | catalogued as COSV71688918; called by muse, mutect2, varscan2
